MMRF case MMRF_2114 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/ed0e8c7b-8254-4166-8983-9af343dedb94

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 53 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 53.6 years (19,573 days); ISS stage: I; Days to last known disease status: 972 days (2.7 years); Days to last follow up: 972 days (2.7 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 30 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 15 days; Days to treatment end: 91 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 37 days; Days to treatment end: 85 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 109 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 169 days; Days to treatment end: 190 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 169 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 204 days; Days to treatment end: 218 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 235 days; Days to treatment end: 235 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: Second line of therapy; Days to treatment start: 236 days; Days to treatment end: 236 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 351 days; Days to treatment end: 435 days (1.2 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6 (ECOG 1): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 17810 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.8 mg/dL; Immunoglobulin G 6.11 g/L; Immunoglobulin A 0.42 g/L; Immunoglobulin M 0.04 g/L; Beta 2 Microglobulin 2 µg/mL; Hemoglobin 4.9 mmol/L; Leukocytes 4.5 ×10⁹/L; Platelets 245 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.43 mmol/L; Albumin 41 g/L; Total Protein 6.4 g/dL; Glucose 7.37 mmol/L.
- Day 85: Serum Free Immunoglobulin Light Chain, Kappa 25.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.81 mg/dL; Immunoglobulin G 4.09 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 2.03 µg/mL; Lactate Dehydrogenase 3.28 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 5.17 ×10⁹/L; Absolute Neutrophil 2.89 ×10⁹/L; Platelets 213 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.35 mmol/L; Albumin 44 g/L; Total Protein 6.1 g/dL; Glucose 8.36 mmol/L.
- Day 179: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 70 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.795 mg/dL; Immunoglobulin G 3.39 g/L; Immunoglobulin A 0.24 g/L; Immunoglobulin M 0.24 g/L; Lactate Dehydrogenase 4.55 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 7.49 ×10⁹/L; Absolute Neutrophil 3.74 ×10⁹/L; Platelets 201 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 5.7 g/dL; Glucose 9.96 mmol/L.
- Day 257 (ECOG 3): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 28.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.075 mg/dL; Immunoglobulin G 2.79 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 0.57 µg/mL; Lactate Dehydrogenase 4.87 µkat/L; Hemoglobin 4.84 mmol/L; Leukocytes 7.9 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 55 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 5.5 g/dL; Glucose 10 mmol/L.
- Day 438: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.23 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.948 mg/dL; Immunoglobulin G 5.76 g/L; Immunoglobulin A 0.91 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 3.88 µkat/L; Hemoglobin 5.52 mmol/L; Leukocytes 4.16 ×10⁹/L; Platelets 221 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.05 mmol/L; Albumin 38 g/L; Total Protein 5.7 g/dL; Glucose 9.35 mmol/L.
- Day 523 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.04 mg/dL; Immunoglobulin G 7.34 g/L; Immunoglobulin A 1.07 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 3.97 µkat/L; Hemoglobin 5.77 mmol/L; Leukocytes 4.23 ×10⁹/L; Platelets 172 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.15 mmol/L; Albumin 40 g/L; Total Protein 5.8 g/dL; Glucose 12 mmol/L.
- Day 615 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.58 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.15 mg/dL; Immunoglobulin G 6.87 g/L; Immunoglobulin A 0.64 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 4.15 µkat/L; Hemoglobin 5.7 mmol/L; Leukocytes 4.27 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 135 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.33 mmol/L; Albumin 41 g/L; Total Protein 6.3 g/dL; Glucose 7.1 mmol/L.
- Day 726: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.18 mg/dL; Immunoglobulin G 7.81 g/L; Immunoglobulin A 0.77 g/L; Immunoglobulin M 0.15 g/L; Hemoglobin 5.02 mmol/L; Leukocytes 4.4 ×10⁹/L; Platelets 165 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.1 mmol/L; Albumin 37 g/L; Total Protein 6 g/dL; Glucose 9.02 mmol/L.
- Day 797 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.59 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.839 mg/dL; Immunoglobulin G 7.01 g/L; Immunoglobulin A 0.87 g/L; Immunoglobulin M 0.08 g/L; Beta 2 Microglobulin 1.8 µg/mL; Lactate Dehydrogenase 4.27 µkat/L; Hemoglobin 5.7 mmol/L; Leukocytes 6.56 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.38 mmol/L; Albumin 44 g/L; Total Protein 6.3 g/dL; Glucose 4.46 mmol/L.
- Day 887: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.881 mg/dL; Immunoglobulin G 9.43 g/L; Immunoglobulin A 0.85 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 3.83 µkat/L; Hemoglobin 5.89 mmol/L; Leukocytes 4.43 ×10⁹/L; Platelets 194 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.15 mmol/L; Albumin 41 g/L; Total Protein 6.3 g/dL; Glucose 8.75 mmol/L.
- Day 972: Hemoglobin 5.7 mmol/L; Leukocytes 5.53 ×10⁹/L; Platelets 156 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.15 mmol/L; Albumin 41 g/L; Total Protein 6.3 g/dL; Glucose 6.55 mmol/L.

Other clinical attributes
- Day -6: Weight: 124 kg; Height: 170 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_2114_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_2114_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
